CCDI case PBBZXT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasal cavity and middle ear.
https://portal.gdc.cancer.gov/cases/9249bef0-f4b1-4cd2-be2a-c1b5bdd3dc41

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Ethmoid sinus; Age at diagnosis: 18.5 years (6,762 days).

Biospecimens (3 samples)
- Sample 0DLZNE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLZOI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLZOQ: Tissue type: Tumor; Specimen type: Solid Tissue.
